Somatic mutation profile of tumor specimen 0DZK5B from CCDI case PBCTZW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 15.2 years (5,556 days).
Specimen 0DZK5B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d54e8d8-de8a-4039-a5ac-286f3490fdfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZK5H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/489ac94b-80c9-435c-b30a-680aee4e1b83

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 184/532 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CBLN1 | c.509A>G p.K170R | Missense Mutation (SNP) | VAF 97/706 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as COSV54653790; called by muse, mutect2, varscan2
- CELSR1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1264525398; called by muse, mutect2, varscan2
- NXPE2 | c.96C>A p.F32L | Missense Mutation (SNP) | VAF 73/502 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1431499755; called by muse, mutect2, varscan2
- PPP1R3A | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 43/347 reads (12%) | catalogued as rs1471160727, COSV52878990; called by muse, mutect2, varscan2
- HIPK3 | c.3369A>G p.S1123= | Silent (SNP) | VAF 24/484 reads (5%) | called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 20/571 reads (4%) | called by muse, mutect2
- HEXA | c.1331-67A>G | Intron (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 24/151 reads (16%) | called by muse, varscan2
